Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7IQ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7IQ-01A (Primary Tumor).

Morphology shows both astrocytic and oligodendroglial differentiation. No evident mitotic activity. Proliferation index 2%.

Diagnosis

Oligoastrocytoma WHO grade II

ICD-O-3
Oligoastrocytoma, grade II
9382/3
Site Brain, supratentorial N/A
C71.0
gw 9/30/13

untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 70bd226f-9a30-4269-b9f4-67111a125fbf (TCGA-S9-A7IQ.2E181A31-FB43-4A8C-87E2-F34AA6B14784.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).